Gene-level copy-number profile of tumor specimen MP2PRT-PAPHHE-TMP1-A from MP2PRT case MP2PRT-PAPHHE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,895 days).
Specimen MP2PRT-PAPHHE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6daa3f48-00a8-4bec-b718-2d96d7d0ade0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPHHE-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/383289f1-89af-4858-9290-27ff86d1fb3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 232; copy number 1: 241; copy number 2: 56,561; copy number 3: 1,150; copy number 4: 198.

Homozygous deletions (total copy number 0; autosomes only): 232 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,027,171–89,254,015, 23 genes (within-gene range 0–1): IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,959,979–90,005,629, 5 genes: IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–1): TRGV5P, TRGV5.
- chr7:142,656,701–142,802,748, 26 genes: TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr12:13,371,089–14,365,503, 15 genes: LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162, AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–1): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,672,308–105,771,405, 5 genes (within-gene range 0–1): ELK2AP, IGHA1, IGHEP1, IGHG1, IGHG3.
- chr14:105,851,705–106,538,344, 118 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,564,375–106,566,555, 2 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50.
- chr14:106,622,357–106,639,657, 6 genes (within-gene range 0–1): IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61.
- chr14:106,675,017–106,715,181, 9 genes (within-gene range 0–1): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 241. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
